Somatic mutation profile of tumor specimen TCGA-D1-A168-01A (aliquot TCGA-D1-A168-01A-31D-A12J-09) from TCGA case TCGA-D1-A168, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,586 days).
Specimen TCGA-D1-A168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c2e6d95-ece8-497c-9184-098bbe2829ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A168-10A (Blood Derived Normal), aliquot TCGA-D1-A168-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d25a336b-8881-4729-90a2-9e5b1a485fac

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193922097, CM950030, COSV54385597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 216/430 reads (50%) | catalogued as rs1060502639, CM072991, COSV63764262; ClinVar: pathogenic; called by muse, mutect2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 29/37 reads (78%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 226/345 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 217/324 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACVR1B | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750117601, COSV57777817; called by muse, varscan2
- ARID1A | c.2021del p.S674Ifs*68 | Frame Shift Del (DEL) | VAF 91/270 reads (34%) | catalogued as COSV61380034; called by mutect2, pindel, varscan2
- ASGR2 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV54690576; called by muse, mutect2, varscan2
- ATPAF2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761788938, COSV58264083; called by muse, mutect2, varscan2
- BBS5 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 158/283 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54753177; called by muse, mutect2, varscan2
- C12orf42 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 135/379 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1039825673, COSV59384416; called by muse, mutect2, varscan2
- CACNA1B | c.6553G>A p.G2185S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.708); catalogued as rs538992240, COSV53111911; called by muse, mutect2, varscan2
- COL3A1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs778497667, COSV58583375; called by muse, mutect2, varscan2
- COL4A1 | c.4006G>A p.V1336I | Missense Mutation (SNP) | VAF 137/326 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs202209298; called by muse, mutect2, varscan2
- DPF3 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV63500718; called by muse, mutect2, varscan2
- ESPNL | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1372072678, COSV58035557; called by muse, mutect2, varscan2
- FAT2 | c.10006G>C p.V3336L | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.238); catalogued as COSV55821841; called by muse, mutect2, varscan2
- FAT4 | c.6865C>T p.R2289* | Nonsense Mutation (SNP) | VAF 118/330 reads (36%) | catalogued as COSV58690942; called by muse, mutect2, varscan2
- ITGAX | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51646950; called by muse, mutect2, varscan2
- KANSL1 | c.2722-2A>T p.X908_splice (on ENST00000574590 / NM_001193465.2; = p.X909_splice on NM_015443.4) | Splice Site (SNP) | VAF 62/151 reads (41%) | catalogued as COSV52241662; called by muse, mutect2, varscan2
- KLK11 | c.348G>T p.E116D (on ENST00000594768 / NM_144947.3; = p.E84D on NM_006853.3) | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV51577491; called by muse, mutect2, varscan2
- MACF1 | c.13118T>C p.L4373P (on ENST00000372915; = p.L2306P on NM_012090.5) | Missense Mutation (SNP) | VAF 103/255 reads (40%) | catalogued as COSV57127167; called by muse, mutect2, varscan2
- MED16 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as rs201618878, COSV54127528; called by muse, mutect2, varscan2
- MXD1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52480069; called by muse, mutect2, varscan2
- MYO1E | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1336143871, COSV55689257; called by muse, mutect2, varscan2
- NEGR1 | c.713del p.G238Dfs*5 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as COSV60829116; called by mutect2, pindel, varscan2
- NOA1 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749952292, COSV51736636; called by muse, mutect2, varscan2
- NONO | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV52138218; called by muse, mutect2, varscan2
- OR2M4 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs761848850, COSV60707174; called by muse, mutect2, varscan2
- PELI3 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57857008; called by muse, mutect2, varscan2
- PIKFYVE | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 223/363 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs779881345, COSV52243181; called by muse, mutect2, varscan2
- PROM1 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71699554; called by muse, mutect2, varscan2
- RABGAP1L | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765110857, COSV52284358; called by muse, mutect2, varscan2
- RBM46 | c.1253_1255del p.T418del | In Frame Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1167649437; called by pindel, varscan2
- ROBO2 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV59909043; called by muse, mutect2, varscan2
- ROBO4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs755801141, COSV60621702; called by muse, mutect2, varscan2
- SENP5 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 234/347 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60208103; called by muse, mutect2, varscan2
- SLC9A7 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs780578762, COSV60380998; called by muse, mutect2, varscan2
- SPOP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV61652701; called by muse, mutect2, varscan2
- SULF1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746174102, COSV52684408; called by muse, mutect2, varscan2
- SZT2 | c.6521C>T p.T2174M (on ENST00000634258 / NM_001365999.1; = p.T2117M on NM_015284.4) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757630324, COSV65167353; called by muse, mutect2, varscan2
- TBC1D2 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV59785762; called by muse, mutect2, varscan2
- TMEM213 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs779847207, COSV59476950; called by muse, mutect2, varscan2
- UFSP2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs772982549, COSV52991894; called by muse, mutect2, varscan2
- USH2A | c.3628C>A p.L1210M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56385473, COSV56403434; called by muse, mutect2, varscan2
- ARID1A | c.4057_4072del p.P1353Rfs*123 | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | called by mutect2, pindel, varscan2
- HNRNPAB | c.703dup p.Y235Lfs*79 (on ENST00000504898; = p.Y235Lfs*32 on NM_004499.4) | Frame Shift Ins (INS) | VAF 44/118 reads (37%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.2607C>T p.G869= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs762047159, COSV50103781; called by muse, mutect2, varscan2
- BMPER | c.1353G>A p.A451= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV51821969; called by muse, mutect2, varscan2
- CYP7A1 | c.489C>T p.T163= | Silent (SNP) | VAF 103/318 reads (32%) | catalogued as rs574513686, COSV56964180; called by muse, mutect2, varscan2
- F5 | c.5367A>G p.R1789= | Silent (SNP) | VAF 114/323 reads (35%) | catalogued as COSV63125170; called by muse, mutect2, varscan2
- FAT3 | c.12225C>T p.C4075= | Silent (SNP) | VAF 77/156 reads (49%) | catalogued as COSV53099935; called by muse, mutect2, varscan2
- LRFN2 | c.1743C>T p.G581= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs147506870; called by muse, mutect2, varscan2
- LRP1 | c.3171G>A p.R1057= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1430474756, COSV54514850; called by muse, mutect2, varscan2
- NOD1 | c.1836C>T p.A612= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56113094; called by muse, mutect2, varscan2
- PEX2 | c.621C>T p.L207= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV63813764; called by muse, mutect2, varscan2
- STXBP5 | c.1878A>G p.G626= | Silent (SNP) | VAF 119/194 reads (61%) | catalogued as COSV51653646; called by muse, mutect2, varscan2
- WNK2 | c.762C>T p.I254= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs576508893, COSV52946418; called by muse, mutect2, varscan2
- WSCD1 | c.1383G>A p.P461= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs146617432; called by muse, mutect2, varscan2
